Somatic mutation profile of tumor specimen C3L-00946-01 (aliquot CPT0027520009) from CPTAC case C3L-00946, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.2 years (23,444 days).
Specimen C3L-00946-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9206c1c8-ab66-4ef9-9a11-81757822fb46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00946-71 (Blood Derived Normal), aliquot CPT0027580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66ad043f-40fe-44d9-bce6-600cce592e75

The open-access MAF lists 1,168 somatic variants for this specimen: 796 protein-altering or splice-affecting, 214 silent, 158 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 530, Silent 214, Frame Shift Del 176, Intron 75, Nonsense Mutation 31, 3'UTR 30, Frame Shift Ins 28, RNA 18, 5'UTR 13, 5'Flank 12, Splice Site 12, Splice Region 11.

Variants (750 of 1,168; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912679, CM080031, COSV55117476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- CUL7 | c.4717C>T p.R1573* | Nonsense Mutation (SNP) | VAF 121/446 reads (27%) | catalogued as rs749509661, CM053191; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.5077C>T p.R1693W | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs863225021, CM053839; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 70/297 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 67/299 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- PAX2 | c.76del p.V26Cfs*3 | Frame Shift Del (DEL) | VAF 38/137 reads (28%) | catalogued as rs75462234, COSV62291007; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 143/298 reads (48%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RP1 | c.3843del p.P1282Lfs*12 | Frame Shift Del (DEL) | VAF 69/390 reads (18%) | catalogued as rs769601671; ClinVar: pathogenic; called by pindel, varscan2
- RYR1 | c.14545G>A p.V4849I | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs118192168, CM021677, COSV62110654; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- SLC16A1 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 123/443 reads (28%) | catalogued as rs606231310, CM1411337, COSV63708941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 27/72 reads (38%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.1186+8T>C | Splice Region (SNP) | VAF 11/171 reads (6%) | catalogued as COSV99907944; called by muse, mutect2
- ABCA10 | c.4106G>A p.G1369E | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52220787; called by muse, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV67016962; called by mutect2, pindel, varscan2
- ABCA7 | c.5449A>G p.I1817V | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1257579951; called by muse, mutect2, varscan2
- ABCB9 | c.1985del p.P662Qfs*19 (on ENST00000280560 / NM_019625.4; = p.P619Qfs*19 on NM_019624.3) | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | catalogued as rs1169625873; called by mutect2, pindel, varscan2
- ABCC1 | c.2509G>A p.V837I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs754975789, COSV100578120; called by muse, mutect2, varscan2
- ABRACL | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766064009; called by muse, mutect2
- ACAN | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs369608360; ClinVar: uncertain significance; called by muse, mutect2
- ACAP2 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1466971128, COSV100461310; called by muse, mutect2, varscan2
- ACAP3 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767716088; called by muse, mutect2, varscan2
- ACHE | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771062715, COSV53816025; called by muse, mutect2, varscan2
- ADAMTSL4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.92); catalogued as rs199599791, COSV55010010; called by muse, mutect2, varscan2
- ADARB2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749880767; called by muse, mutect2, varscan2
- ADD2 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs782349268; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRL1 | c.3784G>A p.G1262R (on ENST00000340736 / NM_001008701.3; = p.G1257R on NM_014921.5) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs776313065; called by muse, mutect2, varscan2
- ADH1A | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52924313, COSV52925495; called by muse, mutect2, varscan2
- AKIRIN2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs1282657029; called by muse, mutect2
- AMBP | c.606_607del p.R202Sfs*21 | Frame Shift Del (DEL) | VAF 52/244 reads (21%) | catalogued as rs772001887; called by pindel, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- ANGPT2 | c.813del p.T272Lfs*29 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as COSV57336527; called by mutect2, pindel, varscan2
- ANKRD36C | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.517); catalogued as rs747763695; called by muse, varscan2
- ANXA6 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374219814, COSV62906263; called by muse, mutect2, varscan2
- APOBR | c.3062del p.P1021Qfs*29 (on ENST00000431282; = p.P1030Qfs*29 on NM_018690.4) | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as COSV60491628; called by mutect2, pindel, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARHGAP35 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV68334980; called by muse, mutect2, varscan2
- ARHGAP35 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1276231338, COSV68328989; called by muse, mutect2, varscan2
- ARHGEF10L | c.2426G>A p.C809Y | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs978483235; called by muse, mutect2
- ARID1A | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61371863; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 42/162 reads (26%) | catalogued as rs758608743; called by mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 15/109 reads (14%) | catalogued as rs753865255; called by mutect2, varscan2
- AS3MT | c.818T>A p.V273D | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100185604; called by muse, mutect2, varscan2
- ASPM | c.4999C>T p.R1667C | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755281471; called by muse, mutect2, varscan2
- ASTN1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1166111973; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 53/226 reads (23%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG2A | c.5663del p.G1888Afs*2 | Frame Shift Del (DEL) | VAF 49/184 reads (27%) | catalogued as COSV100815511; called by mutect2, pindel, varscan2
- ATP2A3 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs138738315; called by muse, mutect2, varscan2
- ATP8A2 | c.2494G>A p.A832T | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1320026816; called by muse, mutect2, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | catalogued as COSV51989295; called by mutect2, pindel, varscan2
- B4GALNT3 | c.1732A>G p.M578V | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753555258; called by muse, mutect2, varscan2
- B4GALNT3 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149737676; called by muse, mutect2
- BEST1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as CM111672, CM991235, COSV57120302; called by muse, mutect2, varscan2
- BRD4 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1265135334; called by muse, mutect2
- BRINP3 | c.1349T>G p.L450R | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV66543126; called by muse, mutect2, varscan2
- BTF3 | c.370C>A p.Q124K (on ENST00000380591 / NM_001037637.1; = p.Q80K on NM_001207.4) | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV100246660; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | catalogued as rs774921343; called by mutect2, pindel
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C8orf48 | c.258dup p.W87Mfs*11 | Frame Shift Ins (INS) | VAF 40/147 reads (27%) | catalogued as rs1447138619; called by mutect2, pindel, varscan2
- CALHM1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375270464; called by muse, mutect2, varscan2
- CARMIL3 | c.3428del p.G1143Afs*85 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs750529250; called by mutect2, pindel, varscan2
- CASQ2 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV99797945; called by muse, mutect2, varscan2
- CBLN4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756451061, COSV50352834; called by muse, mutect2, varscan2
- CCDC70 | c.151dup p.I51Nfs*72 | Frame Shift Ins (INS) | VAF 39/136 reads (29%) | catalogued as rs752919705; called by mutect2, pindel, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 39/162 reads (24%) | catalogued as rs762194001; called by mutect2, varscan2
- CEACAM21 | c.784C>T p.R262* (on ENST00000401445 / NM_001098506.4; = p.R261* on NM_033543.6) | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | catalogued as rs568421412, COSV51816111; called by muse, mutect2, varscan2
- CHTF18 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777573884; called by muse, mutect2, varscan2
- CIAO3 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1008474423, COSV52400873, COSV99284592; called by muse, mutect2, varscan2
- CLUL1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 52/212 reads (25%) | catalogued as rs763977404, COSV58112700; called by muse, mutect2, varscan2
- CNKSR3 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs375414125; called by muse, mutect2, varscan2
- COL16A1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs183118523; called by muse, mutect2, varscan2
- COL18A1 | c.2714C>A p.P905H (on ENST00000359759 / NM_130444.3; = p.P670H on NM_030582.4) | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100700826; called by muse, mutect2
- COL27A1 | c.2968G>A p.V990M | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs758039055; called by muse, mutect2, varscan2
- COL4A3 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 121/461 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV67420659, COSV67420717; called by muse, mutect2, varscan2
- CPO | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1348510725; called by muse, mutect2, varscan2
- CR1 | c.4690C>T p.R1564W | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs370698774; called by muse, mutect2, varscan2
- CRELD1 | c.119del p.P40Rfs*52 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs755273029; called by mutect2, pindel, varscan2
- CSMD2 | c.6409G>A p.A2137T | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.877); catalogued as COSV53939067; called by muse, varscan2
- CTCF | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50470542; called by muse, varscan2
- CTSK | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 85/419 reads (20%) | catalogued as rs764168526; called by mutect2, pindel, varscan2
- CTTNBP2 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 57/222 reads (26%) | catalogued as COSV50428280, COSV99353953; called by muse, mutect2, varscan2
- DAB2IP | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.712); catalogued as rs199630836; called by muse, mutect2, varscan2
- DAB2IP | c.2603C>T p.A868V (on ENST00000408936; = p.A840V on NM_032552.3) | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs759770964; called by muse, mutect2, varscan2
- DCHS2 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV100251054; called by muse, mutect2, varscan2
- DLC1 | c.2885G>A p.S962N (on ENST00000276297 / NM_001348081.2; = p.S525N on NM_006094.5) | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs201102622; called by muse, mutect2, varscan2
- DNAH5 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs780758815, COSV99453032; ClinVar: uncertain significance; called by muse, mutect2
- DNAH8 | c.1609-1G>A p.X537_splice | Splice Site (SNP) | VAF 29/101 reads (29%) | catalogued as rs1175745110, COSV59447313; called by muse, mutect2
- DNAJC13 | c.6259G>A p.A2087T | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs375745713; called by muse, mutect2, varscan2
- DOCK5 | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs139516143, COSV52412606; called by muse, mutect2, varscan2
- DPP6 | c.1300-1G>T p.X434_splice (on ENST00000377770 / NM_001364500.2; = p.X372_splice on NM_001936.5) | Splice Site (SNP) | VAF 30/116 reads (26%) | catalogued as COSV59626928; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DSEL | c.1355del p.G452Dfs*7 | Frame Shift Del (DEL) | VAF 24/224 reads (11%) | catalogued as COSV59491427; called by mutect2, pindel
- DTNA | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 135/478 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1160999097, COSV52000112; called by muse, mutect2, varscan2
- DYSF | c.4226G>A p.R1409H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758688467, COSV50269245, COSV99245257; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 66/233 reads (28%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF2D | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs200255569; called by muse, mutect2, varscan2
- EPHA5 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56639694; called by muse, mutect2
- ETFRF1 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100334423; called by muse, mutect2, varscan2
- FAM126B | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs372270432; called by muse, mutect2, varscan2
- FAM167A | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV52667726; called by muse, mutect2, varscan2
- FAM47B | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760524670; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs748967872; called by mutect2, varscan2
- FCRL6 | c.132T>A p.N44K | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs1481522498; called by muse, varscan2
- FKBP6 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99333583; called by muse, mutect2
- FLNB | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.384); catalogued as rs373579468; called by muse, mutect2, varscan2
- FLNC | c.6817G>A p.A2273T | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs372251350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP2 | c.1232del p.N411Tfs*14 | Frame Shift Del (DEL) | VAF 50/199 reads (25%) | catalogued as rs775387591; called by mutect2, pindel, varscan2
- FRS3 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs544857762, COSV52486128, COSV99443261; called by muse, mutect2, varscan2
- GABBR1 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs765285063; called by muse, mutect2, varscan2
- GAL3ST3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1328810262, COSV61749103; called by muse, mutect2
- GALM | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs116100345; called by muse, mutect2, varscan2
- GAN | c.1225A>G p.M409V | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs747981312; called by muse, mutect2, varscan2
- GAN | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 91/299 reads (30%) | catalogued as rs764354626; called by muse, mutect2, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs761897305; called by mutect2, varscan2
- GDI2 | c.1314_1316del p.K438del | In Frame Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs768266050; called by pindel, varscan2
- GGT6 | c.1460G>A p.C487Y (on ENST00000574154 / NM_001122890.3; = p.C455Y on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1465281333, COSV54596948; called by muse, mutect2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | catalogued as rs771881138; called by mutect2, varscan2
- GIPC3 | c.706-1G>A p.X236_splice | Splice Site (SNP) | VAF 20/400 reads (5%) | catalogued as rs1447257064; called by muse, mutect2
- GJA4 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs765548562; called by muse, mutect2, varscan2
- GJC2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as rs776485630; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAT1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 129/503 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1325267297, COSV50028212, COSV50038972; called by muse, mutect2, varscan2
- GPANK1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs369234510; called by mutect2, varscan2
- GPRC6A | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs751882459; called by muse, mutect2, varscan2
- HAL | c.1829A>C p.Q610P | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs1248734701; called by muse, mutect2, varscan2
- HAPLN4 | c.705dup p.T236Dfs*9 | Frame Shift Ins (INS) | VAF 24/142 reads (17%) | catalogued as rs778286592; called by mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs57105282; called by mutect2, varscan2
- HGS | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV61268775, COSV61270851; called by muse, mutect2, varscan2
- HHAT | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.129); catalogued as rs1408361995; called by muse, mutect2, varscan2
- HMCN2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1554927616, COSV70279748; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs761272507; called by mutect2, varscan2
- HOOK3 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs372716570, COSV56880265; called by muse, varscan2
- HPRT1 | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as CM890072; called by muse, mutect2, varscan2
- HS3ST5 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57139857; called by muse, mutect2, varscan2
- HSD17B4 | c.1702C>T p.R568C (on ENST00000414835 / NM_001199291.3; = p.R543C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs775326908; called by muse, mutect2, varscan2
- HTR7 | c.1421del p.K474Rfs*3 (on ENST00000336152 / NM_019859.4; = p.G442Vfs*6 on NM_000872.5) | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | catalogued as COSV53287248; called by mutect2, pindel, varscan2
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, mutect2, varscan2
- HUWE1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs782306178; called by muse, mutect2, varscan2
- ICE1 | c.6776C>T p.A2259V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV56824312; called by muse, mutect2, varscan2
- IGHE | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.72); catalogued as rs539647133; called by muse, mutect2, varscan2
- IGHV4-39 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs775104315; called by muse, mutect2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs760925109; called by pindel, varscan2
- INSRR | c.3802del p.A1268Pfs*110 | Frame Shift Del (DEL) | VAF 115/633 reads (18%) | catalogued as COSV100947553; called by mutect2, pindel, varscan2
- INTS9 | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as rs763636831; called by muse, mutect2, varscan2
- IQCN | c.3536G>A p.G1179D | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100828299, COSV62748633; called by muse, mutect2, varscan2
- ITM2B | c.93del p.D32Tfs*30 | Frame Shift Del (DEL) | VAF 51/166 reads (31%) | catalogued as rs746700992; called by mutect2, pindel, varscan2
- KCNQ2 | c.2572G>A p.G858S (on ENST00000359125 / NM_172107.4; = p.G830S on NM_004518.6) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs756609768, COSV100609901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KHDRBS1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1354857143; called by muse, mutect2, varscan2
- KIAA2026 | c.5855G>C p.S1952T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs959769140; called by muse, mutect2, varscan2
- KIF26B | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832949; called by muse, mutect2, varscan2
- KIFC3 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101109290; called by muse, mutect2, varscan2
- KLF3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV54710638; called by muse, mutect2, varscan2
- KLHDC1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200431928, COSV63778506; called by muse, mutect2, varscan2
- KLHL32 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100987147; called by muse, mutect2
- KLHL34 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1183599618; called by muse, mutect2, varscan2
- KMT2A | c.3486G>T p.Q1162H | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63287868; called by muse, mutect2, varscan2
- KRTAP10-1 | c.282del p.C95Afs*233 | Frame Shift Del (DEL) | VAF 179/686 reads (26%) | catalogued as COSV59961454; called by mutect2, pindel, varscan2
- LAMA1 | c.6475G>A p.G2159S | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761061272, COSV67534942; called by muse, mutect2, varscan2
- LAMB2 | c.3628C>T p.R1210C | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs753602785; called by muse, mutect2, varscan2
- LANCL3 | c.192dup p.L65Afs*33 | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | catalogued as rs782221297; called by mutect2, varscan2
- LANCL3 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs782037401; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 29/92 reads (32%) | catalogued as rs775423572; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 49/202 reads (24%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPCAT4 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as rs774698476, COSV59218479; called by muse, mutect2, varscan2
- LRBA | c.6657_6658del p.E2219Dfs*3 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs727503779; called by pindel, varscan2
- LRFN4 | c.1630del p.A544Pfs*80 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1555021490; called by mutect2, varscan2
- LRIG2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs770298704; called by muse, mutect2, varscan2
- LRRC41 | c.2004G>T p.Q668H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100586176; called by muse, mutect2, varscan2
- LRRC52 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 59/277 reads (21%) | catalogued as rs750985878, COSV54232327; called by muse, mutect2, varscan2
- LRRC8A | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771228754, COSV52187071; called by muse, mutect2, varscan2
- LRRK2 | c.6028G>T p.A2010S | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as CM1314328; called by muse, mutect2, varscan2
- LVRN | c.1390del p.S464Lfs*15 | Frame Shift Del (DEL) | VAF 36/133 reads (27%) | catalogued as rs756702147; called by mutect2, pindel, varscan2
- MACF1 | c.13943C>A p.P4648H (on ENST00000372915; = p.P2581H on NM_012090.5) | Missense Mutation (SNP) | VAF 13/222 reads (6%) | catalogued as COSV99247147; called by muse, mutect2
- MADD | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1195327978, COSV100211611; called by muse, mutect2, varscan2
- MAGEB3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64396804; called by muse, mutect2, varscan2
- MAGEC3 | c.502del p.E168Rfs*45 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs1295601131; called by mutect2, pindel
- MAML2 | c.2316_2318del p.L773del | In Frame Del (DEL) | VAF 102/306 reads (33%) | catalogued as rs759982826; called by pindel, varscan2
- MAP4K4 | c.2766G>T p.K922N (on ENST00000347699 / NM_001242559.2; = p.K840N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100155866; called by muse, mutect2, varscan2
- MB | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs746664660; called by muse, mutect2, varscan2
- MBNL1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as rs755423235; called by muse, mutect2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 57/186 reads (31%) | catalogued as rs759225724; called by mutect2, varscan2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 44/178 reads (25%) | catalogued as rs1193719928; called by mutect2, pindel, varscan2
- MLXIP | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs367724204, COSV59836538; called by muse, mutect2, varscan2
- MMRN1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236756752, COSV53334893; called by muse, mutect2, varscan2
- MPLKIP | c.227del p.G76Afs*77 | Frame Shift Del (DEL) | VAF 40/276 reads (14%) | catalogued as rs1562783168, CD151121; called by mutect2, pindel, varscan2
- MRPS22 | c.1070C>T p.A357V (on ENST00000310776 / NM_001363893.1; = p.A358V on NM_020191.4) | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV60351062; called by muse, mutect2, varscan2
- MRTFA | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.715); catalogued as rs764365801, COSV62932099; called by muse, varscan2
- MRTFA | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as COSV62935272; called by muse, varscan2
- MST1R | c.3145G>A p.V1049M | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.959); catalogued as rs777576135; called by muse, mutect2, varscan2
- MTO1 | c.1982G>A p.R661H (on ENST00000370300 / NM_133645.3; = p.R636H on NM_012123.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751695333, COSV64773281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.34244C>T p.T11415I | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); catalogued as rs758013267; called by muse, mutect2, varscan2
- MUC5B | c.13648G>A p.A4550T | Missense Mutation (SNP) | VAF 139/554 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV101500840; called by muse, mutect2, varscan2
- MYH13 | c.2134G>T p.G712* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as COSV52823048, COSV52826127; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 49/235 reads (21%) | catalogued as rs867690748; called by muse, mutect2, varscan2
- MYO7B | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373706003; called by muse, mutect2
- MYO7B | c.6070del p.D2024Tfs*68 | Frame Shift Del (DEL) | VAF 43/203 reads (21%) | catalogued as COSV61443858; called by mutect2, pindel, varscan2
- NBPF10 | c.11065del p.R3689Efs*32 | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | catalogued as rs781875736; called by mutect2, varscan2
- NCKAP1L | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53212119; called by muse, mutect2, varscan2
- NEB | c.10220C>T p.A3407V | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1473256084; called by muse, varscan2
- NEDD4 | c.2546G>A p.R849Q (on ENST00000508342 / NM_001284338.1; = p.R430Q on NM_006154.4) | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as rs368172324; called by muse, mutect2, varscan2
- NELL1 | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1398526297, COSV54267932; called by muse, mutect2, varscan2
- NES | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763081922, COSV63961383; called by muse, mutect2, varscan2
- NFATC2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs772861578; called by muse, mutect2, varscan2
- NFYA | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs775882054; called by muse, mutect2, varscan2
- NHSL2 | c.797C>T p.T266I (on ENST00000510661; = p.T632I on NM_001013627.2) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as rs1485324588; called by muse, mutect2, varscan2
- NIBAN2 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371085080, COSV64823855; called by muse, mutect2, varscan2
- NIF3L1 | c.1030C>T p.R344* (on ENST00000409020 / NM_001369444.1; = p.R317* on NM_021824.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | catalogued as rs777077429, COSV100677444; called by muse, mutect2, varscan2
- NOA1 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51735783; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 54/202 reads (27%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH4 | c.4469G>A p.R1490Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs527962523, COSV66678665; called by muse, mutect2
- NRF1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs761369981; called by muse, mutect2, varscan2
- NSD1 | c.5891del p.K1964Rfs*5 | Frame Shift Del (DEL) | VAF 13/144 reads (9%) | catalogued as CM1513390; called by mutect2, pindel
- NTRK1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 115/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750477154, COSV62326152; called by muse, mutect2, varscan2
- NUF2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs199764107; called by muse, mutect2, varscan2
- OBSCN | c.10129G>A p.A3377T | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs1324969569, COSV52770562; called by muse, mutect2
- OR5M11 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV101602033; called by muse, mutect2, varscan2
- OR6K3 | c.400A>G p.M134V (on ENST00000368146; = p.M118V on NM_001005327.2) | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759238455; called by muse, mutect2, varscan2
- OR7C2 | c.311dup p.I105Hfs*17 | Frame Shift Ins (INS) | VAF 56/214 reads (26%) | catalogued as rs1392370943; called by mutect2, varscan2
- OSBPL5 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs767854463; called by muse, mutect2, varscan2
- PAEP | c.204del p.E69Rfs*67 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | catalogued as COSV99478840; called by mutect2, pindel, varscan2
- PAPPA2 | c.3845del p.L1282* | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | catalogued as rs1558553713; called by mutect2, pindel, varscan2
- PCDHA13 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 130/406 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782588313; called by muse, mutect2, varscan2
- PCDHA13 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 61/644 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV56476186; called by muse, mutect2
- PCDHA9 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.41); catalogued as rs782607638, COSV65323269; called by mutect2, varscan2
- PCDHGA6 | c.1107del p.Q370Kfs*9 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | catalogued as COSV53946532; called by mutect2, pindel, varscan2
- PDLIM2 | c.817G>A p.A273T (on ENST00000397760; = p.A523T on NM_021630.6) | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141780037, COSV99747990; called by muse, mutect2, varscan2
- PEX14 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs1386505247, COSV100749980; called by muse, mutect2, varscan2
- PGAP2 | c.587C>T p.S196L (on ENST00000463452 / NM_001346398.2; = p.S257L on NM_014489.4) | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs766716423, COSV53466672; called by muse, mutect2, varscan2
- PHEX | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs867137730; called by muse, mutect2, varscan2
- PHKA1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 106/560 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs148540646, COSV59809628; called by muse, varscan2
- PHKB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs377351270; called by muse, mutect2
- PIGZ | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53013521; called by muse, mutect2, varscan2
- PIM3 | c.638dup p.E214Gfs*84 | Frame Shift Ins (INS) | VAF 10/79 reads (13%) | catalogued as rs1404401779; called by mutect2, pindel, varscan2
- PKDREJ | c.6649C>T p.P2217S | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.195); catalogued as COSV53550272; called by muse, mutect2, varscan2
- PKDREJ | c.6263G>T p.G2088V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53552847; called by muse, mutect2, varscan2
- PKP2 | c.1368del p.K456Nfs*3 | Frame Shift Del (DEL) | VAF 89/339 reads (26%) | catalogued as rs1393661338, CD061458; called by mutect2, pindel, varscan2
- PLAA | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1314988669; called by muse, mutect2
- PLEC | c.5308C>T p.R1770C (on ENST00000322810 / NM_201380.4; = p.R1660C on NM_000445.5) | Missense Mutation (SNP) | VAF 38/421 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782816453, COSV100513355; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHA6 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs746671918; called by muse, mutect2, varscan2
- PLXNA2 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs754654582, COSV65446024; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNA3 | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs782001830; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs953293505; called by mutect2, varscan2
- PMF1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771971437, COSV60771389; called by muse, mutect2, varscan2
- PML | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as rs372931853; called by muse, mutect2, varscan2
- POLE | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs374200895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLG | c.116_118del p.Q39del | In Frame Del (DEL) | VAF 66/279 reads (24%) | catalogued as rs763663907; called by pindel, varscan2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2, varscan2
- POMGNT2 | c.1238del p.G413Afs*53 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs780368344; called by mutect2, pindel, varscan2
- POTEF | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 85/434 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV62540726; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 52/186 reads (28%) | catalogued as rs763475304; called by mutect2, varscan2
- PPP1R35 | c.235-7C>T | Splice Region (SNP) | VAF 24/78 reads (31%) | catalogued as rs1165466426; called by muse, mutect2, varscan2
- PPP2R2B | c.878G>T p.G293V (on ENST00000394409; = p.G359V on NM_181674.2) | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100356470, COSV60761202; called by muse, mutect2, varscan2
- PRAMEF14 | c.1368del p.C457Afs*39 | Frame Shift Del (DEL) | VAF 83/315 reads (26%) | catalogued as rs1553186813; called by mutect2, pindel, varscan2
- PRDM10 | c.2732C>T p.T911M | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs768574831, COSV58805327; called by muse, mutect2, varscan2
- PSKH1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs201432888, COSV52123548; called by muse, mutect2, varscan2
- PSMC5 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1415435145; called by muse, mutect2, varscan2
- PTCH2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777212373; called by muse, mutect2, varscan2
- PTPRC | c.1958_1959del p.F653Sfs*3 | Frame Shift Del (DEL) | VAF 54/259 reads (21%) | catalogued as rs1346325559; called by mutect2, pindel, varscan2
- PWWP2B | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100535842; called by muse, mutect2, varscan2
- PYGB | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs562479236; called by muse, mutect2, varscan2
- QARS1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549522450; called by muse, mutect2, varscan2
- QSER1 | c.3295G>A p.G1099S (on ENST00000399302; = p.G1228S on NM_001076786.3) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1380446909; called by muse, mutect2, varscan2
- RAB19 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1164371377, COSV52044732; called by muse, mutect2, varscan2
- RAB34 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910197266; called by muse, mutect2
- RADIL | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs752332791, COSV68201754; called by muse, mutect2, varscan2
- RALBP1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1469364485, COSV99192058; called by muse, mutect2, varscan2
- RASSF5 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs781811232, COSV100795044, COSV100795339; called by muse, varscan2
- RAVER1 | c.1555G>T p.G519W (on ENST00000615032; = p.G675W on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781694037; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM46 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs143408830, COSV99908219; called by muse, mutect2, varscan2
- RCL1 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs769268289, COSV67755914; called by muse, mutect2, varscan2
- RERE | c.3249dup p.S1084Vfs*19 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | catalogued as rs745806637; ClinVar: uncertain significance; called by mutect2, varscan2
- RERE | c.2897del p.P966Lfs*4 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs5772316; called by mutect2, varscan2
- RHOBTB2 | c.920del p.G307Afs*88 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs753391613; called by mutect2, pindel, varscan2
- RIMS4 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs745355556; called by muse, mutect2, varscan2
- RIN3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs773928478, COSV104370358; called by muse, mutect2, varscan2
- RIN3 | c.2531C>T p.T844M | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1314534855; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RP1L1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373409421; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404635350; called by muse, mutect2, varscan2
- RPS6KC1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.301); catalogued as rs770341753, COSV100873932; called by muse, mutect2, varscan2
- RSPH6A | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762469971, COSV55574238; called by muse, mutect2, varscan2
- RTN4RL2 | c.875del p.P292Rfs*232 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs750876328; called by mutect2, pindel, varscan2
- RYR2 | c.6370G>A p.G2124S | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as COSV100772080; called by muse, mutect2
- RYR2 | c.11189G>A p.R3730Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060500157, COSV100769899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs765136101; called by mutect2, varscan2
- SCN9A | c.3749A>G p.Y1250C (on ENST00000303354; = p.Y1239C on NM_002977.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs1558973293, COSV100313593; called by muse, mutect2, varscan2
- SEMA4C | c.1975del p.L659Wfs*87 | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | catalogued as rs1436989321; called by mutect2, pindel, varscan2
- SEMA6C | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 71/395 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772706332; called by muse, mutect2, varscan2
- SERPINB2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763497538, COSV55091290; called by muse, mutect2, varscan2
- SHANK1 | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs750134749; called by muse, mutect2, varscan2
- SHKBP1 | c.134_136del p.F45del | In Frame Del (DEL) | VAF 42/184 reads (23%) | catalogued as rs767470501; called by pindel, varscan2
- SIPA1L1 | c.4700A>G p.Q1567R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs760621071; called by muse, mutect2, varscan2
- SKI | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs775800782, COSV66014031; ClinVar: uncertain significance; called by muse, mutect2
- SLC30A3 | c.613del p.H205Tfs*260 | Frame Shift Del (DEL) | VAF 50/200 reads (25%) | catalogued as rs745429257; called by mutect2, varscan2
- SLC39A4 | c.1784G>A p.G595D (on ENST00000301305 / NM_001374839.1; = p.G570D on NM_017767.3) | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM073356; called by muse, mutect2, varscan2
- SLC4A3 | c.2675C>T p.T892M | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398058468, COSV56095381; called by muse, mutect2, varscan2
- SLC5A1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 101/432 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs200727862; called by muse, mutect2, varscan2
- SLC7A11 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1006772141; called by muse, mutect2, varscan2
- SLC9A3R1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs375193779; called by muse, mutect2, varscan2
- SLC9A8 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867374600; called by muse, mutect2
- SMAD2 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1291358405, COSV51027821, COSV51061114; called by muse, mutect2, varscan2
- SMTN | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760671053, COSV60779167; called by muse, mutect2, varscan2
- SNX21 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61132444; called by muse, mutect2, varscan2
- SPEG | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.805); catalogued as rs966754296; called by muse, mutect2, varscan2
- SPTLC3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs375500511, COSV65463690; called by muse, mutect2, varscan2
- SSMEM1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs140752649; called by muse, mutect2, varscan2
- ST3GAL5 | c.622G>A p.A208T (on ENST00000377332; = p.A248T on NM_003896.4) | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1409195681, COSV60386255; called by muse, mutect2, varscan2
- STIM1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56156914; called by muse, mutect2, varscan2
- STK10 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs761809175, COSV51571497; called by muse, mutect2, varscan2
- STK32B | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778314748; called by muse, mutect2, varscan2
- SWT1 | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.781); catalogued as COSV62257538; called by muse, mutect2, varscan2
- SYNPO2 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1430340370, COSV61112985, COSV61119992; called by muse, mutect2
- SZT2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758311269; called by muse, mutect2, varscan2
- SZT2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs764100978, COSV63034890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1B | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as rs11540127, COSV99722621; called by muse, mutect2, varscan2
- TANC2 | c.1790del p.L597Wfs*4 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1284876631; called by mutect2, pindel, varscan2
- TBC1D9 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs753536091, COSV71307528; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 33/116 reads (28%) | catalogued as rs763438715; called by mutect2, varscan2
- TECR | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 96/442 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as COSV53108369; called by muse, varscan2
- TEKT5 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752263208, COSV99296389; called by muse, mutect2, varscan2
- TENM3 | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.977); catalogued as COSV69321621; called by muse, mutect2, varscan2
- TGIF2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV65836258; called by muse, mutect2, varscan2
- THSD7A | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1352267683; called by muse, mutect2, varscan2
- TIMP2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1235478767, COSV99430092; called by muse, mutect2
- TMEM74B | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs867466760, COSV67892076; called by muse, mutect2, varscan2
- TMEM9 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757757323; called by muse, mutect2, varscan2
- TMPRSS12 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1190855708; called by muse, mutect2, varscan2
- TMPRSS13 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1400869297, COSV70626416; called by muse, mutect2
- TMTC2 | c.1869+7C>T | Splice Region (SNP) | VAF 61/194 reads (31%) | catalogued as rs781656835; called by muse, mutect2, varscan2
- TNK2 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.647); catalogued as rs555967551; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TPR | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs181905365; called by muse, mutect2, varscan2
- TRAFD1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV57505716; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIM7 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.98); catalogued as rs1298696444; called by muse, mutect2, varscan2
- TRPM2 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs569048007; called by muse, mutect2, varscan2
- TTC22 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1210334928; called by muse, mutect2, varscan2
- TUBA3E | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as rs143099002; called by muse, mutect2, varscan2
- U2AF2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100454430; called by muse, varscan2
- UBAP1 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs753301456, COSV52657646; called by muse, mutect2, varscan2
- UNC45B | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs368981219; called by muse, mutect2, varscan2
- UNC80 | c.9205C>T p.R3069C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1401772812, COSV99779542; called by muse, mutect2, varscan2
- USP34 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | catalogued as COSV68401118; called by muse, mutect2
- UTF1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58678096; called by muse, mutect2, varscan2
- VPS13C | c.10660G>T p.G3554* (on ENST00000644861 / NM_020821.3; = p.G3511* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 37/138 reads (27%) | catalogued as COSV51414446; called by muse, mutect2, varscan2
- WASHC2A | c.2812-1G>T p.X938_splice | Splice Site (SNP) | VAF 89/339 reads (26%) | catalogued as rs1387222481; called by muse, mutect2, varscan2
- WDCP | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs778442393; called by muse, mutect2, varscan2
- WDR17 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572703; called by muse, mutect2, varscan2
- WDR7 | c.4141G>A p.D1381N | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs145833111; called by muse, mutect2, varscan2
- WDR81 | c.4771G>A p.G1591R (on ENST00000409644 / NM_001163809.2; = p.G540R on NM_152348.4) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs761103438, COSV58487024; called by muse, mutect2, varscan2
- WDR86 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs1379280616; called by muse, mutect2, varscan2
- WDR93 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV51537028; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 58/114 reads (51%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 16/172 reads (9%) | catalogued as rs762079039; called by mutect2, pindel
- WNT4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 81/365 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs759526796; called by muse, mutect2, varscan2
- WRAP53 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 22/238 reads (9%) | catalogued as rs761173739; called by muse, mutect2
- WSCD1 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as rs145775221; called by muse, mutect2, varscan2
- WWC3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs1169982725; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 70/284 reads (25%) | catalogued as rs779864368; called by mutect2, varscan2
- ZBBX | c.975del p.K325Nfs*55 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs773705832; called by mutect2, pindel, varscan2
- ZBED4 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs868834816, COSV53467685; called by muse, mutect2, varscan2
- ZBED9 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV71729231; called by muse, mutect2, varscan2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 69/240 reads (29%) | catalogued as rs760469533; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFP57 | c.529del p.C177Afs*25 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | catalogued as rs1272756745; called by mutect2, pindel, varscan2
- ZKSCAN5 | c.2072dup p.N691Kfs*5 | Frame Shift Ins (INS) | VAF 56/255 reads (22%) | catalogued as rs556762260; called by mutect2, varscan2
- ZNF107 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV61331169; called by muse, mutect2, varscan2
- ZNF268 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs753366583; called by muse, mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF395 | c.700del p.H234Tfs*43 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs768191349; called by mutect2, pindel
- ZNF407 | c.509del p.P170Rfs*13 | Frame Shift Del (DEL) | VAF 52/202 reads (26%) | catalogued as COSV55245772; called by mutect2, pindel, varscan2
- ZNF429 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs762632896, COSV61915460; called by muse, mutect2, varscan2
- ZNF469 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1420971751; called by muse, mutect2, varscan2
- ZNF557 | c.236T>C p.V79A (on ENST00000414706 / NM_001044388.2; = p.V86A on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.539); catalogued as rs760424239; called by muse, mutect2, varscan2
- ZNF579 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1448990006, COSV100329215; called by muse, varscan2
- ZNF684 | c.393dup p.S132Ifs*3 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | catalogued as rs760649229; called by mutect2, varscan2
- ZNF737 | c.183del p.K61Nfs*3 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs1224733412, COSV71199512; called by mutect2, pindel, varscan2
- ZNF878 | c.138dup p.W47Mfs*7 | Frame Shift Ins (INS) | VAF 25/66 reads (38%) | catalogued as rs775158654; called by mutect2, varscan2
- ZRSR2 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57063909; called by muse, mutect2, varscan2
- ABCA10 | c.3967T>A p.L1323M | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- ABCA13 | c.12818G>A p.S4273N | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ABCB9 | c.1844C>T p.A615V (on ENST00000280560 / NM_019625.4; = p.A572V on NM_019624.3) | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, varscan2
- ABR | c.1542G>T p.K514N (on ENST00000302538 / NM_021962.5; = p.K477N on NM_001092.5) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AC011462.1 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 117/408 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AC092143.1 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 100/343 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ACSF3 | c.1516G>T p.G506* | Nonsense Mutation (SNP) | VAF 66/275 reads (24%) | called by muse, mutect2, varscan2
- ADD2 | c.1214C>A p.T405K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ADGRE1 | c.2141G>A p.C714Y | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADRA2C | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGO3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- AHNAK2 | c.14498C>A p.P4833H | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK2 | c.10090G>A p.D3364N | Missense Mutation (SNP) | VAF 134/452 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ALDH7A1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD44 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANO9 | c.2275dup p.A759Gfs*96 | Frame Shift Ins (INS) | VAF 35/148 reads (24%) | called by mutect2, pindel, varscan2
- APBB1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- APBB3 | c.1250C>T p.A417V (on ENST00000357560 / NM_133173.2; = p.A424V on NM_006051.3) | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ARHGEF10 | c.2801A>G p.Q934R (on ENST00000398564; = p.Q909R on NM_014629.4) | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF10L | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARID3A | c.1497C>A p.A499= | Splice Region (SNP) | VAF 57/187 reads (30%) | called by muse, mutect2, varscan2
- ARMC2 | c.2237_2238del p.V746Gfs*2 | Frame Shift Del (DEL) | VAF 36/178 reads (20%) | called by pindel, varscan2
- ARMH2 | c.124_128delinsG p.K42Efs*23 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | called by pindel, varscan2*
- ARSI | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATF6 | c.488del p.N163Mfs*3 | Frame Shift Del (DEL) | VAF 32/167 reads (19%) | called by mutect2, pindel
- ATP2B2 | c.2414C>T p.A805V (on ENST00000352432; = p.A771V on NM_001683.5) | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP2B4 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 82/393 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ATP8B1 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AXIN1 | c.1922del p.K641Rfs*64 | Frame Shift Del (DEL) | VAF 87/328 reads (27%) | called by mutect2, pindel, varscan2
- BCL9L | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BPIFB1 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BPIFB4 | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- BRPF1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BTBD3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.96); called by muse, varscan2
- BTRC | c.1603G>T p.A535S (on ENST00000370187 / NM_033637.4; = p.A499S on NM_003939.5) | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C16orf96 | c.643del p.T215Pfs*30 | Frame Shift Del (DEL) | VAF 33/204 reads (16%) | called by mutect2, pindel, varscan2
- C19orf44 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C19orf44 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- C1QC | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C5orf63 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- C7orf25 | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CACNG2 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.833); called by muse, mutect2
- CACTIN | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAPN14 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CCDC114 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- CCDC14 | c.373+2_373+3insG | Splice Region (INS) | VAF 13/59 reads (22%) | called by mutect2, varscan2*
- CCDC15 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 82/294 reads (28%) | called by muse, varscan2
- CCDC183 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CCSAP | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDC42BPA | c.3869T>C p.V1290A (on ENST00000334218 / NM_001366019.2; = p.V1277A on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CDC73 | c.830A>T p.D277V | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by mutect2, varscan2
- CDH19 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CDIN1 | c.841G>T p.A281S (on ENST00000437989; = p.A183S on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, varscan2
- CELSR2 | c.6893T>C p.L2298P | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.112); called by muse, mutect2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 66/296 reads (22%) | called by mutect2, pindel, varscan2
- CHSY1 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIART | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLTRN | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2
- CNTLN | c.535-7_535-1delinsCCAC p.X179_splice | Splice Site (DEL) | VAF 15/66 reads (23%) | called by pindel, varscan2*
- COL6A1 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COLEC12 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CP | c.2647G>A p.V883M | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- CPSF4 | c.744T>C p.C248= | Splice Region (SNP) | VAF 68/225 reads (30%) | called by muse, mutect2, varscan2
- CPSF6 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPT1A | c.1187A>G p.Q396R | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CREG1 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 94/340 reads (28%) | called by mutect2, varscan2
- CTNND1 | c.2594_2595del p.Y865* (on ENST00000399050 / NM_001085458.2; = p.Y859* on NM_001331.3) | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by pindel, varscan2
- CTTN | c.1565T>G p.I522S | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CXCR5 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CYP2S1 | c.1117del p.R373Afs*63 | Frame Shift Del (DEL) | VAF 29/123 reads (24%) | called by mutect2, pindel, varscan2
- DBR1 | c.819del p.S274Vfs*25 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel
- DCAF15 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.087); called by muse, varscan2
- DEPP1 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- DHRS13 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 33/158 reads (21%) | called by mutect2, pindel, varscan2
- DHX34 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP1 | c.1414T>G p.F472V | Missense Mutation (SNP) | VAF 75/399 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- DNAAF2 | c.1617G>T p.Q539H | Missense Mutation (SNP) | VAF 120/429 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH6 | c.11931G>A p.W3977* | Nonsense Mutation (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- DNAJC10 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- DPYSL2 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSTYK | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYM | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.4840G>T p.D1614Y | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EFCAB6 | c.3364A>G p.T1122A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGFL6 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF2AK2 | c.462dup p.Q155Tfs*5 | Frame Shift Ins (INS) | VAF 18/111 reads (16%) | called by mutect2, pindel, varscan2
- ELP1 | c.2737-3del | Splice Region (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- ERGIC2 | c.954_955del p.C319Wfs*22 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by pindel, varscan2
- ESYT2 | c.1285G>A p.V429I (on ENST00000613624; = p.V353I on NM_020728.3) | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.386); called by muse, mutect2
- EVX1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC6B | c.2124G>C p.Q708H | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- EXTL1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAAH2 | c.953del p.L318* | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- FAM120C | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FAM135B | c.3531A>T p.E1177D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FARP2 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FBLN5 | c.1310T>G p.I437S | Missense Mutation (SNP) | VAF 117/437 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FBN3 | c.4319del p.G1440Vfs*14 | Frame Shift Del (DEL) | VAF 49/154 reads (32%) | called by mutect2, pindel, varscan2
- FBXO45 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW10 | c.1809dup p.K604Efs*55 | Frame Shift Ins (INS) | VAF 58/224 reads (26%) | called by mutect2, pindel, varscan2
- FCGBP | c.8465A>C p.E2822A | Missense Mutation (SNP) | VAF 88/570 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FEM1A | c.1320A>T p.E440D | Missense Mutation (SNP) | VAF 141/475 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- FLT3LG | c.290dup p.L97Ffs*151 (on ENST00000594009 / NM_001204503.2; = p.L97Ffs*210 on NM_001459.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 65/238 reads (27%) | called by mutect2, pindel, varscan2
- FN1 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- FYB1 | c.2005G>T p.G669* (on ENST00000351578 / NM_199335.5; = p.G715* on NM_001465.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- GAS2L3 | c.1873del p.T625Hfs*62 | Frame Shift Del (DEL) | VAF 56/194 reads (29%) | called by mutect2, pindel, varscan2
- GATA1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIGYF1 | c.1909T>A p.L637M | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GIPR | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 85/378 reads (22%) | called by pindel, varscan2
- GLIPR1L1 | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- GLIS1 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GLP2R | c.1436A>T p.K479M | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GNAQ | c.834_836del p.L279del | In Frame Del (DEL) | VAF 26/120 reads (22%) | called by pindel, varscan2
- GNL3L | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- GOLGA3 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- GPATCH8 | c.2145del p.K715Nfs*394 | Frame Shift Del (DEL) | VAF 51/199 reads (26%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.1949G>T p.S650I | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPI | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIA2 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- GRID2 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 76/262 reads (29%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRK5 | c.1519del p.V507Cfs*9 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- GRWD1 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- GSTP1 | c.351T>A p.D117E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C3 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GUCY1A2 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- H2AC17 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HECW1 | c.1359del p.S454Vfs*75 | Frame Shift Del (DEL) | VAF 54/179 reads (30%) | called by mutect2, pindel, varscan2
- HECW2 | c.4608-2A>G p.X1536_splice | Splice Site (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- HELB | c.2465del p.N822Ifs*19 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- HEPACAM | c.100dup p.V34Gfs*61 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- HMGCS2 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HPS6 | c.2292del p.S765Afs*40 | Frame Shift Del (DEL) | VAF 151/611 reads (25%) | called by mutect2, pindel, varscan2
- HSD17B12 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- HSF1 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HSPA6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2A | c.1289dup p.N431Efs*11 | Frame Shift Ins (INS) | VAF 34/139 reads (24%) | called by mutect2, varscan2
- HUWE1 | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- IGKV1D-16 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 25/517 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2
- IL12B | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IL17RA | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 135/450 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPP5D | c.3275C>T p.A1092V (on ENST00000445964 / NM_001017915.3; = p.A1091V on NM_005541.5) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel
- IQSEC2 | c.1925del p.P642Rfs*80 (on ENST00000642864 / NM_001111125.3; = p.P437Rfs*80 on NM_015075.2) | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- ISLR2 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITPR3 | c.2023_2025del p.E675del | In Frame Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel
- JAG1 | c.3558del p.N1187Tfs*25 | Frame Shift Del (DEL) | VAF 46/178 reads (26%) | called by mutect2, pindel, varscan2
- JAG2 | c.1418del p.G473Afs*7 | Frame Shift Del (DEL) | VAF 122/449 reads (27%) | called by mutect2, pindel, varscan2
- JAG2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- JAKMIP3 | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JMJD1C | c.5989G>T p.D1997Y | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, varscan2
- KALRN | c.8249C>A p.P2750H (on ENST00000360013 / NM_001024660.4; = p.P1053H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KAT14 | c.1527del p.F509Lfs*13 | Frame Shift Del (DEL) | VAF 53/238 reads (22%) | called by mutect2, pindel, varscan2
- KATNA1 | c.500del p.K167Rfs*8 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- KIF15 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, varscan2
- KIF19 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- KIF26B | c.5102G>A p.G1701D | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.1709del p.G570Vfs*29 | Frame Shift Del (DEL) | VAF 68/342 reads (20%) | called by mutect2, pindel, varscan2
- KIT | c.1188T>A p.N396K | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLK5 | c.796T>C p.C266R | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRF2 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KMT2D | c.15784G>T p.A5262S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KRT33B | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- KRT8 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 84/298 reads (28%) | called by muse, mutect2, varscan2
- LAMA2 | c.4890G>C p.E1630D | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.845); called by muse, mutect2
- LAMA3 | c.6517G>A p.V2173M (on ENST00000313654 / NM_198129.4; = p.V564M on NM_000227.6) | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- LAMA3 | c.7900T>G p.L2634V (on ENST00000313654 / NM_198129.4; = p.L1025V on NM_000227.6) | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.309); called by muse, mutect2
- LAMB1 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LARGE1 | c.895del p.V299* | Frame Shift Del (DEL) | VAF 87/383 reads (23%) | called by mutect2, pindel, varscan2
- LARGE1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARP1B | c.2257dup p.M753Nfs*3 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- LCE3D | c.242dup p.S82Lfs*61 | Frame Shift Ins (INS) | VAF 44/216 reads (20%) | called by mutect2, pindel, varscan2
- LDB3 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- LEO1 | c.1929_1931del p.E643del | In Frame Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- LEO1 | c.1590C>A p.C530* | Nonsense Mutation (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- LMBR1 | c.1205C>A p.P402H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMO4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- LMTK3 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2
- LOXL2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPCAT4 | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LRFN1 | c.1187del p.P396Rfs*75 | Frame Shift Del (DEL) | VAF 30/156 reads (19%) | called by mutect2, pindel, varscan2
- LSR | c.859C>T p.H287Y (on ENST00000361790; = p.H268Y on NM_015925.6) | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP1 | c.2533del p.T845Hfs*9 (on ENST00000404816 / NM_206943.4; = p.T519Hfs*9 on NM_000627.4) | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- LY6L | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYST | c.3450G>T p.K1150N | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); called by muse, mutect2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | called by mutect2, varscan2
- MAN1A2 | c.1192G>T p.G398* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- MAN2B1 | c.2358T>C p.D786= | Splice Region (SNP) | VAF 16/515 reads (3%) | called by muse, mutect2
- MAP3K12 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K4 | c.3732del p.F1244Lfs*4 | Frame Shift Del (DEL) | VAF 41/194 reads (21%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.4543A>G p.T1515A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP3K5 | c.1298T>A p.I433N | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARK4 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MBD3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MCM2 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MCMBP | c.189T>A p.N63K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MCRIP1 | c.58del p.R20Afs*56 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | called by mutect2, pindel, varscan2
- MICAL1 | c.437del p.R146Pfs*20 | Frame Shift Del (DEL) | VAF 44/153 reads (29%) | called by mutect2, pindel, varscan2
- MICALL2 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MMEL1 | c.614G>T p.R205M | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- MOB3B | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 66/250 reads (26%) | called by muse, varscan2
- MOSPD2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MRC2 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MRPL46 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- MS4A1 | c.577A>C p.I193L | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MTUS1 | c.1388del p.N463Tfs*10 | Frame Shift Del (DEL) | VAF 49/169 reads (29%) | called by mutect2, pindel, varscan2
- MTX3 | c.811T>G p.S271A (on ENST00000512528 / NM_001363818.2; = p.S210A on NM_001167741.2) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MYBL2 | c.1222del p.S408Lfs*50 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- MYC | c.419C>T p.A140V (on ENST00000377970; = p.A155V on NM_002467.6) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NALCN | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, varscan2
- NARS1 | c.221A>C p.Q74P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NCAPH | c.1404del p.D469Ifs*25 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- NHS | c.3695C>T p.T1232I | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX2-4 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NNAT | c.235del p.Q79Nfs*2 (on ENST00000649309 / NM_001322802.2; = p.N81Tfs*51 on NM_005386.4) | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- NPHP3 | c.3896del p.G1299Vfs*17 | Frame Shift Del (DEL) | VAF 40/187 reads (21%) | called by mutect2, pindel, varscan2
- NRXN1 | c.2792del p.F931Sfs*8 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- NSD3 | c.3595T>G p.F1199V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NSUN4 | c.830G>T p.R277M | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- OAS1 | c.433del p.V145Wfs*15 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- OPA1 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- OR1S1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2H1 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- OR4C46 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- OR4K1 | c.258del p.F86Lfs*27 | Frame Shift Del (DEL) | VAF 36/272 reads (13%) | called by pindel, varscan2
- OR51E1 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OR7C1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | called by mutect2, pindel, varscan2
- OS9 | c.1133del p.K378Rfs*6 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- OSR1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OTOF | c.4593C>A p.N1531K (on ENST00000272371 / NM_194248.3; = p.N764K on NM_004802.4) | Missense Mutation (SNP) | VAF 124/570 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- OTOG | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVCH1 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PACS2 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH11X | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX2 | c.1028T>C p.L343S | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4B | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDP2 | c.671del p.G224Dfs*2 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | called by mutect2, pindel, varscan2
- PDX1 | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PDZD7 | c.391del p.D131Tfs*6 | Frame Shift Del (DEL) | VAF 24/280 reads (9%) | called by mutect2, pindel
- PEDS1 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PEX26 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 154/574 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PHACTR2 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PHLDB1 | c.3438dup p.K1147Efs*42 | Frame Shift Ins (INS) | VAF 65/248 reads (26%) | called by mutect2, pindel, varscan2
- PI4KA | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PIK3AP1 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CB | c.1659T>A p.N553K | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PITPNM3 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PKHD1L1 | c.3605G>T p.R1202M | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PKLR | c.585del p.N196Tfs*31 | Frame Shift Del (DEL) | VAF 78/345 reads (23%) | called by mutect2, pindel, varscan2
- PLA2G4E | c.236del p.N79Mfs*8 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | called by mutect2, pindel, varscan2
- PLA2R1 | c.53del p.G18Afs*42 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- PLXNA1 | c.2050C>A p.H684N | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- POLR3B | c.634del p.S212Afs*7 | Frame Shift Del (DEL) | VAF 66/214 reads (31%) | called by mutect2, pindel, varscan2
- POT1 | c.703-3del | Splice Region (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PPIG | c.36del p.F12Lfs*115 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | called by mutect2, varscan2
- PPIP5K1 | c.4167G>T p.E1389D (on ENST00000396923; = p.E1364D on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R18 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP4R3A | c.1161C>G p.Y387* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- PPP4R3C | c.2357C>A p.T786K | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP6R1 | c.2108C>A p.P703H | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF20 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2
- PRDM15 | c.1536C>A p.S512R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PRX | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- PTPN14 | c.2952del p.L986Cfs*17 | Frame Shift Del (DEL) | VAF 61/267 reads (23%) | called by mutect2, pindel, varscan2
- PTPRQ | c.5486dup p.N1829Kfs*14 (on ENST00000616559; = p.N1787Kfs*14 on NM_001145026.2) | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- PTPRT | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- PXN | c.1048del p.V350Sfs*21 (on ENST00000228307 / NM_001080855.3; = p.V316Sfs*21 on NM_002859.4) | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- R3HDML | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD50 | c.1504del p.M502Wfs*3 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.2395A>G p.N799D | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM19 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM4 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RCOR3 | c.158del p.K53Sfs*72 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- RERE | c.1532T>G p.F511C | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RGS3 | c.1712T>G p.L571R (on ENST00000350696 / NM_001282923.2; = p.L459R on NM_017790.4) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RGSL1 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RHOXF2B | c.381del p.L128Wfs*44 | Frame Shift Del (DEL) | VAF 68/148 reads (46%) | called by mutect2, varscan2
- RIMS1 | c.3994T>A p.C1332S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.3); called by muse, varscan2
- RNF14 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- RNF6 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ROCK2 | c.3028_3031del p.E1010* | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- RTF1 | c.236_237del p.S79* | Frame Shift Del (DEL) | VAF 29/127 reads (23%) | called by pindel, varscan2
- RTN4 | c.1202A>C p.E401A | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RUNDC1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- S100PBP | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SAMD3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, varscan2
- SBF2 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SCN5A | c.4232C>T p.A1411V (on ENST00000333535 / NM_198056.3; = p.A1410V on NM_000335.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEC61B | c.162del p.M55Cfs*22 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- SECISBP2L | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEPTIN7 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SETD1A | c.4147A>T p.S1383C | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.926); called by muse, varscan2
- SF3A3 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SGIP1 | c.1390del p.R464Gfs*34 | Frame Shift Del (DEL) | VAF 43/168 reads (26%) | called by mutect2, pindel, varscan2
- SH2B1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SH3GLB2 | c.625-2A>G p.X209_splice | Splice Site (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- SH3KBP1 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH3PXD2A | c.1488G>A p.W496* (on ENST00000369774 / NM_001365079.1; = p.W468* on NM_014631.2) | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SHBG | c.522dup p.L175Afs*39 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, varscan2
- SIX5 | c.1026del p.V343Sfs*124 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- SLC25A18 | c.760_763del p.K254Afs*27 | Frame Shift Del (DEL) | VAF 48/219 reads (22%) | called by mutect2, pindel, varscan2
- SLC27A4 | c.862del p.L288Sfs*19 | Frame Shift Del (DEL) | VAF 94/355 reads (26%) | called by mutect2, pindel, varscan2
- SLC39A8 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- SLC4A10 | c.1151A>G p.Y384C (on ENST00000446997 / NM_001354461.2; = p.Y354C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A2 | c.1281-1G>T p.X427_splice | Splice Site (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- SLC6A20 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SLC9C2 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO5A1 | c.663del p.Y222Tfs*6 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- SLTM | c.1783del p.R595Efs*16 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | called by mutect2, pindel, varscan2
- SP100 | c.209del p.K70Rfs*68 | Frame Shift Del (DEL) | VAF 36/153 reads (24%) | called by mutect2, pindel, varscan2
- SP4 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SPATA31A3 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 146/909 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPATA48 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPINK5 | c.3182del p.P1061Rfs*21 | Frame Shift Del (DEL) | VAF 111/489 reads (23%) | called by mutect2, pindel, varscan2
- SPTLC3 | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPTSSA | c.138del p.M47Wfs*46 | Frame Shift Del (DEL) | VAF 50/206 reads (24%) | called by mutect2, pindel, varscan2
- SRPK3 | c.763del p.Q255Rfs*17 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by pindel, varscan2
- STARD9 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIL | c.3624del p.K1208Nfs*4 | Frame Shift Del (DEL) | VAF 89/310 reads (29%) | called by mutect2, pindel, varscan2
- STMND1 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SUPT3H | c.426C>A p.N142K (on ENST00000371460 / NM_181356.3; = p.N131K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- SYNE2 | c.2031del p.K677Nfs*30 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by mutect2, pindel, varscan2
- SZT2 | c.4481-1G>T p.X1494_splice (on ENST00000634258 / NM_001365999.1; = p.X1437_splice on NM_015284.4) | Splice Site (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- TAC4 | c.310+2T>C p.X104_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- TACC2 | c.848del p.P283Qfs*18 | Frame Shift Del (DEL) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- TAF3 | c.1461del p.N488Tfs*34 | Frame Shift Del (DEL) | VAF 29/233 reads (12%) | called by mutect2, pindel, varscan2
- TCF4 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 27/566 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TCIRG1 | c.504-7C>T | Splice Region (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- TCOF1 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 36/137 reads (26%) | called by mutect2, pindel, varscan2
- TENM3 | c.4898A>G p.D1633G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TEX10 | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- TFDP1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TGFB1 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGFBRAP1 | c.2268G>A p.M756I | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TH | c.268G>A p.A90T (on ENST00000381178 / NM_199292.3; = p.A59T on NM_000360.4) | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TIPRL | c.468del p.F156Lfs*13 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- TLR8 | c.2037del p.F679Lfs*25 (on ENST00000218032 / NM_138636.5; = p.F697Lfs*25 on NM_016610.4) | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- TMEFF2 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- TMEM101 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM131 | c.3976del p.L1326Sfs*26 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, varscan2
- TMEM200C | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNS2 | c.696G>A p.K232= (on ENST00000314250 / NM_170754.4; = p.K242= on NM_015319.2) | Splice Region (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- TOP3A | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53I13 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRIM5 | c.1371T>G p.H457Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TRIP13 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TTC16 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TTC29 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL11 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TXNDC11 | c.2694G>T p.Q898H (on ENST00000356957 / NM_001303447.2; = p.Q871H on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2
418 further variants in this file (46 protein-altering or splice-affecting, 214 silent, 158 other) are not listed here.
